Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABL4, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABL4-TTP1-A (Primary Tumor).

[page 1 of 2]
CDDP-YP-ABL4-01-PR

Previous exams
Previous exams exist.

Clinical Data and Diagnostic Questions
Pulmonary neoplasm (right lung) with intracerebral metastases.

Material description

1. Lymph node n.121 surgical biopsy
2. Lower pulmonary lobe, right lung/ surgical sample
3. Bronchus at the section level/ surgical biopsy
4. Lymph node n..7/ surgical biopsy
5. Lymph node n.11/ surgical biopsy
6. Lymph node n.10/ surgical biopsy
7. Lymph node n. 4/ surgical biopsy
8. Lymph node n.3/ surgical biopsy
9. Middle lobe sample/ surgical sample

ICD-0-3

Adenocarcinoma, NOS 8140/3
Site: (R) lung, lower lobe C34.3

ICD-10

C34.31

hw
2/12/16

Macro description

1. Anthracotic lymph node of 1.5 cm
2. 12 x 117 cm pulmonary lower lobe, right lung with metal suture of 6 cm along the medial side.
The visceral pleura appears retracted for the presence of underlying nodular lesion of 3,5 x 2.5 x 4 ,cm polycyclic margins. The lesion is made up of whitish lardaceous tissue that shows large cystic cavitation.
3. Small whitish fragment of 0.7 cm
4. Lymph node package of 4.7 x 1.5 x 3.5 cm made up of lardaceous tissue
5. Three anthracotic fragments
6. Lymph node of 2 x 1 cm
7. Lymph node of 2 x 1 cm
8. Lymph node of 2.5 x 1 cm
9. Fragment of pulmonary subpleural parenchyma with mechanical suture of 5 cm along the longer side

Micro description

1. 5.6.7.8. The lymph nodes n.12, n. 11, n. 10, n. 4, n. 3 are anthracotic and negative for metastatic localizations.
2. The extensive sampling of the lesion macroscopically described shows malignant epithelial neoplastic process. It is made up of elements of large size with wide cytoplasm, weakly eosinophil, more often clear, vesicular nucleus, irregular, markedly pleomorphic, fitted with one or larger eosinophil nuclei. There are also giant multinucleated elements.
The elements are arranged individually in tubules, glands, in nests and aggregates of variable size; there are focal papillary aspects. The mucus secretion and the presence of eosinophil globules related to surfactant appears very abundant.
We observe mitoses, necrotic foci, vascular intratumoral invasions. The neoplasm infiltrates diffusely the

[page 2 of 2]
pulmonary parenchyma and the above visceral pleura. Single elements or arranged in small aggregates and papillae are present also in the surrounding scattered alveoli, The thin patch of parietal pleura adherent appears congested and characterized by reactive follicular hyperplasia.

The index of nuclear proliferation determined with the antibody MIB1 (KI67) is approximately 20%; the protein is expressed in about 60% of the neoplastic nuclei.

The pulmonary not neoplastic parenchyma shows pneumonia of obstructive type and bronchiolitis of respiratory type .

Surgical margin free of neoplasm

3.The fragment under examination refers to the bronchial wall and is negative for neoplastic infiltration

4.The lymph node package macroscopically described corresponds to massive lymph node and perilymphnodal metastases of poorly differentiated adenocarcinoma with the morphological characters as described under 2. There are foci of necrosis, perilymphnodal vascular invasions

9. The samples show pulmonary subpleural parenchyma characterized by bronchiolitis of respiratory type and modest blackish anthracotic pigment. No evidence of neoplasm

Conclusions add Histopathological Diagnosis

1. 5.6.7.8 Lymph node anthracosis
2. Poorly differentiated adenocarcinoma infiltrating the pulmonary parenchyma and the visceral pleura. Intratumoural vascular invasions. Pneumonia of obstructive type and bronchiolitis of respiratory type. Surgical margin free.
3. Bronchus of section negative for neoplasm
4. Lymph node and perilymphnodal metastases of poorly differentiated adenocarcinoma
9. No evidence of neoplasm.

Staging pTNM: MISSING

Source: NCI Genomic Data Commons file 3c789736-71d1-4d4e-8bc2-96993f57ac22 (CDDP-ABL4-TTP1.0883978C-803B-487D-8549-6DC3BB28F627.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).